Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6531, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6531-01A (Primary Tumor).

Examination: Histopathological examination

Material: **1. Partial resection of organ – colon and caecum**

Physician in charge:

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the hepatic flexure**

Examination performed on:

Macroscopic description:

25 cm length of the large intestine with perintestinal fat tissue of 25 x 8 x 2cm. Omentum sized 12 x 10 cm.

Edge-thickened ulceration sized 4 x 3 cm in the mucosa.

The lesion covers 100% of the intestine circumference, located 12 cm from the proximal cut end and 8 cm from the distal cut end.

The lesion macroscopically infiltrates the perintestinal tissue.

Microscopic description:

Adenocarcinoma tubulare (G2).

Infiltratio carcinomatosa telae adiposae pericolicae.

Intestine ends clear of neoplastic lesions.

Lymphonodulitis reactiva (No IV).

Histopathological diagnosis:

Adenocarcinoma tubulare coli. Tubular adenocarcinoma of the colon,
(G2; Dukes B; Astler-Coller B2; pT3; pN0).

Source: NCI Genomic Data Commons file 088f6a94-d143-4a5b-b27b-f7561a4a9566 (TCGA-D5-6531.4CABC827-8E16-4590-AA3B-017C6BD3A399.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).